CCDI case PBCVKW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/115a8fc0-07a2-451a-b641-dd924cf5f8bf

Demographics
Sex at birth: female.

Biospecimens (2 samples)
- Sample 0E1BNR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E1BOK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
